Surgical pathology report (de-identified scan), TCGA case TCGA-61-1722, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1722-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTUM, BIOPSY –
BENIGN OMENTAL ADIPOSE TISSUE.

PART 2: ADNEXA, LEFT, LEFT SALPINGO-OOPHORECTOMY –
A. HIGH GRADE PAPILLARY SEROUS OVARIAN ADENOCARCINOMA, NUCLEAR GRADE 3.
B. NO EVIDENCE OF CAPSULAR INVASION.
C. BENIGN LEFT FALLOPIAN TUBE.

PART 3: ADNEXA, RIGHT, SALPINGO-OOPHORECTOMY –
A. HIGH GRADE PAPILLARY SEROUS OVARIAN ADENOCARCINOMA, NUCLEAR GRADE 3.
B. NO EVIDENCE OF CAPSULAR INVASION.
C. RIGHT FALLOPIAN TUBE WITH TUBAL INTRAEPITHELIAL CARCINOMA AND SUBMUCOSAL INVASIVE ADENOCARCINOMA (SLIDE 3F).

COMMENT:

Strong immunohistochemical staining with P53 in atypical tubal epithelium and adjacent invasive adenocarcinoma supports presence of tubal intraepithelial carcinoma in slide 3F from the right fallopian tube and raises the possibility of a tubal origin for high grade serous adenocarcinoma present in both ovaries. Diffuse strong WT1 nuclear staining in the adenocarcinoma in 2A and 3C supports the diagnosis of serous adenocarcinoma.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS	
TUMOR LOCATION:	Bilateral
PROCEDURE:	Bilateral Salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 3.5 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Solid (3)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	> or = 25 (3)
VASCULAR INVASION:	No
TUMOR CAPSULE:	Intact
SURFACE IMPLANTS:	Not present
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	No
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 0
T STAGE, PATHOLOGIC:	pT1b
N STAGE, PATHOLOGIC:	pNX
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	I

Source: NCI Genomic Data Commons file 74204b1a-8d6c-4a24-adcb-68ae69be5e2d (TCGA-61-1722.059421F4-442E-4E81-A726-7A8486C74CDC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).